TCGA case TCGA-18-3416 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Princess Margaret Hospital (Canada). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6eb61cab-8e83-4c18-a59a-ae0985ec9d2e

Demographics
Sex at birth: male; Country of residence at enrollment: Canada; Age at index: 83 years; Vital status: Dead; Days to death: 973 days (2.7 years).

Diagnoses (4)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 83.3 years (30,435 days); Year of diagnosis: 2006; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 973 days (2.7 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Upper limb, NOS; Classification of tumor: Prior primary.
3. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Thorax, NOS; Laterality: Left; Classification of tumor: Prior primary.
4. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 85.9 years (31,375 days); Days to diagnosis: 940 days (2.6 years); Prior treatment: Yes.

Follow-up (3 entries)
- Day 940 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 940 days (2.6 years); Evidence of progression type: Biopsy with Histologic Confirmation.
- Days to follow up: 956 days (2.6 years); Disease response: With Tumor.
- Days to follow up: 973 days (2.7 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 40.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-18-3416-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.5; Intermediate dimension: 0.5; Shortest dimension: 0.4.
  Slide TCGA-18-3416-01A-01-BS1: Section location: Bottom; Percent tumor cells: 88; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 7; Percent lymphocyte infiltration: 25.
  Slide TCGA-18-3416-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 7; Percent lymphocyte infiltration: 25.
- Sample TCGA-18-3416-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-18-3416-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.6; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Upper.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Left Chest; Other malignancy histological type: Melanoma.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Arm; Other malignancy histological type: Melanoma.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy melanoma of the left chest. Prior malignancy melanoma of the arm. Unknown treatment history.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 973 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 973 days; disease-free interval: event (new tumor event after initially disease-free), 940 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 940 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-18-3416-01A-01D-0978-01): tumor purity 0.51, ploidy 2.99, whole-genome doublings 1.
